Gene-level copy-number profile of tumor specimen CDDP-ABIZ-TTP2-A from CDDP_EAGLE case CDDP-ABIZ, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67 years.
Specimen CDDP-ABIZ-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 289c0793-152a-430f-a24c-56d7471b1f89.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABIZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/8f66ddd7-02a2-4937-ae1c-86e7e5b8757a

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 527; copy number 1: 21; copy number 2: 502; copy number 3: 94; copy number 4: 25,526; copy number 5: 203; copy number 6: 25,479; copy number 7: 233; copy number 8: 5,133; copy number 9: 271; copy number 10: 124; copy number 11: 161; copy number 12: 385; copy number 14: 57; copy number 15: 6; copy number 17: 28; copy number 20: 122; copy number 27: 8; copy number 31: 3; copy number 72: 7; copy number 92: 10; copy number 141: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,748,514–39,810,097, 2 genes: GLIDR, BX664615.1.
- chr9:40,105,822–40,153,147, 4 genes: AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:64,498,517–64,498,745, 1 gene: AL773524.1.
- chr9:64,817,870–65,285,209, 6 genes: AL359955.1, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5.
- chr18:47,390–73,545, 2 genes: TUBB8B, AP001005.3.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 242 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,680,609–52,692,999, 1 gene, copy number 14: AC104066.3.
- chr6:109,288,440–109,443,919, 8 genes, copy number 27: AL359711.1, PTCHD3P3, RNY3P11, RPL7P28, CD164, AL359711.2, PPIL6, SMPD2.
- chr10:7,559,270–9,287,057, 21 genes, copy number 17: ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709.
- chr10:18,940,501–23,194,245, 69 genes, copy number 14–17 (broad region; genes not listed).
- chr10:32,446,140–32,882,874, 1 gene, copy number 20 (within-gene range 8–20): CCDC7.
- chr10:34,965,069–34,966,259, 1 gene, copy number 141: PRDX2P2.
- chr10:35,247,025–35,572,669, 1 gene, copy number 92 (within-gene range 7–92): CCNY.
- chr10:35,314,552–35,800,920, 9 genes, copy number 92: AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5.
- chr14:24,399,003–24,657,774, 10 genes, copy number 31–72: NYNRIN, CBLN3, KHNYN, SDR39U1, AL132800.1, CMA1, CTSG, AL136018.1, GZMH, GZMB.
- chr14:33,924,227–40,390,547, 121 genes, copy number 20 (within-gene range 6–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
